Somatic mutation profile of tumor specimen MMRF_1308_2_BM_CD138pos (aliquot MMRF_1308_2_BM_CD138pos_T1_KBS5U_K11928) from MMRF case MMRF_1308, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.3 years (19,463 days).
Specimen MMRF_1308_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8aaec2b-9192-4bba-b05a-96d00177cfca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1308_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1308_1_PB_Whole_C3_KAS5U_L02457; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8196d117-800f-4a6b-b9ba-a7871cc7f536

The open-access MAF lists 96 somatic variants for this specimen: 23 protein-altering or splice-affecting, 12 silent, 61 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 30, Missense Mutation 18, Intron 16, Silent 12, 5'UTR 6, 5'Flank 5, 3'Flank 3, Frame Shift Del 2, Nonsense Mutation 1, RNA 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SHOC2 | c.4A>G p.S2G | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as rs267607048, CM095445, COSV54624833; ClinVar: pathogenic; called by muse, varscan2
- CCDC146 | c.2221C>T p.R741C | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768291542; called by muse, mutect2
- GLT8D2 | c.322T>C p.F108L | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV62563234; called by muse, mutect2, varscan2
- LRP2 | c.2247C>G p.D749E | Missense Mutation (SNP) | VAF 62/135 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV55550911; called by muse, mutect2, varscan2
- OTOF | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs1558509951; called by muse, mutect2
- PRRC2C | c.4642C>T p.Q1548* (on ENST00000367742; = p.Q1546* on NM_015172.4) | Nonsense Mutation (SNP) | VAF 11/238 reads (5%) | catalogued as COSV58913679; called by muse, mutect2
- TMSB4X | c.100+1G>A p.X34_splice | Splice Site (SNP) | VAF 49/66 reads (74%) | catalogued as COSV101020357; called by muse, mutect2, varscan2
- TRPM7 | c.1048A>G p.I350V | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.096); catalogued as rs1443943384, COSV57918557; called by muse, mutect2, varscan2
- CUBN | c.8624A>G p.D2875G | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2
- IGKJ5 | chr2:88860550 del TAGTGAAAAATTACTTACGTT | Missense Mutation (DEL) | VAF 42/161 reads (26%) | called by pindel, varscan2
- KRT26 | c.280C>A p.L94M | Missense Mutation (SNP) | VAF 77/215 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LEO1 | c.1206A>C p.E402D | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- MAP3K2 | c.1599_1602del p.I533Mfs*19 | Frame Shift Del (DEL) | VAF 20/117 reads (17%) | called by mutect2, pindel, varscan2
- MIGA2 | c.1643_1644insCAACCCAGAC p.L549Nfs*71 | Frame Shift Ins (INS) | VAF 47/116 reads (41%) | called by mutect2, pindel, varscan2
- OR1M1 | c.490G>T p.A164S | Missense Mutation (SNP) | VAF 32/339 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.012); called by muse, mutect2
- OR7D4 | c.906A>C p.E302D | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- RNF168 | c.979_980del p.V327Lfs*7 | Frame Shift Del (DEL) | VAF 62/188 reads (33%) | called by pindel, varscan2
- SLC45A1 | c.1273G>T p.A425S | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SRSF2 | c.6C>G p.S2R | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- TACSTD2 | c.83C>T p.T28M | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2
- TFCP2L1 | c.620A>T p.H207L | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- TNFAIP8L3 | c.859C>A p.L287I | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.123); called by muse, mutect2
- ZNF280C | c.1475A>T p.H492L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- ACSL3 | c.228T>G p.G76= | Silent (SNP) | VAF 4/87 reads (5%) | called by muse, mutect2
- AL669918.1 | c.2448T>C p.P816= | Silent (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- CDR1 | c.198C>T p.D66= | Silent (SNP) | VAF 58/219 reads (26%) | called by muse, mutect2, varscan2
- FAM200A | c.735A>C p.R245= | Silent (SNP) | VAF 10/93 reads (11%) | called by muse, mutect2, varscan2
- HAPLN1 | c.426T>A p.I142= | Silent (SNP) | VAF 8/75 reads (11%) | called by muse, mutect2, varscan2
- IGLL5 | c.57T>A p.G19= | Silent (SNP) | VAF 20/55 reads (36%) | called by muse, mutect2, varscan2
- INSYN2A | c.90C>T p.Y30= | Silent (SNP) | VAF 17/198 reads (9%) | catalogued as rs778825802, COSV54760441; called by muse, mutect2
- LINGO1 | c.1014C>A p.R338= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV62438452; called by muse, mutect2, varscan2
- MLXIP | c.2349G>A p.L783= | Silent (SNP) | VAF 13/31 reads (42%) | called by muse, mutect2, varscan2
- NEFM | c.1242A>C p.T414= | Silent (SNP) | VAF 6/107 reads (6%) | called by muse, mutect2
- ZDHHC5 | c.72A>G p.L24= | Silent (SNP) | VAF 5/137 reads (4%) | called by muse, mutect2
- ZNF804A | c.444T>C p.C148= | Silent (SNP) | VAF 56/151 reads (37%) | called by muse, mutect2, varscan2
- ADAMTSL1 | c.474+60T>G | Intron (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
- ADGRL2 | c.*338T>C | 3'UTR (SNP) | VAF 21/57 reads (37%) | called by muse, mutect2, varscan2
- AL662791.2 | n.217A>G | RNA (SNP) | VAF 8/198 reads (4%) | called by muse, mutect2
- ALX4 | c.*1450C>T | 3'UTR (SNP) | VAF 13/83 reads (16%) | called by muse, mutect2, varscan2
- AMER2 | chr13:25164224 G>A | 3'Flank (SNP) | VAF 13/114 reads (11%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499405 C>T | 5'Flank (SNP) | VAF 27/69 reads (39%) | catalogued as rs185612860; called by muse, mutect2, varscan2
- BCL7A | chr12:122021275 C>T | 5'Flank (SNP) | VAF 49/127 reads (39%) | catalogued as rs765420246, COSV55847946, COSV55851575; called by muse, mutect2, varscan2
- C1orf122 | chr1:37807248 A>T | 5'Flank (SNP) | VAF 7/155 reads (5%) | called by muse, mutect2
- CBR1 | c.289+31A>C | Intron (SNP) | VAF 41/103 reads (40%) | called by muse, mutect2, varscan2
- CCDC81 | c.-165A>G | 5'UTR (SNP) | VAF 13/117 reads (11%) | called by mutect2, varscan2
- CDH26 | c.-222G>A | 5'UTR (SNP) | VAF 41/102 reads (40%) | catalogued as rs758760930; called by muse, mutect2, varscan2
- CERS4 | c.468+42C>T | Intron (SNP) | VAF 38/81 reads (47%) | called by muse, mutect2, varscan2
- CTH | c.*261G>A | 3'UTR (SNP) | VAF 20/62 reads (32%) | called by muse, mutect2, varscan2
- DNM1 | c.2535-1672C>T | Intron (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- DRAM1 | c.*1810C>A | 3'UTR (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- DSG4 | c.-22C>T | 5'UTR (SNP) | VAF 25/491 reads (5%) | catalogued as rs747998720; called by muse, mutect2
- EED | c.-187C>T | 5'UTR (SNP) | VAF 20/38 reads (53%) | called by muse, mutect2, varscan2
- EGR1 | c.-95A>T | 5'UTR (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2, varscan2
- ESRRA | c.*747A>C | 3'UTR (SNP) | VAF 12/75 reads (16%) | called by muse, mutect2, varscan2
- FNIP1 | c.92+80T>C | Intron (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2, varscan2
- FST | c.953-184del | Intron (DEL) | VAF 29/83 reads (35%) | catalogued as rs1412468031; called by mutect2, pindel, varscan2
- GINS3 | c.*251_*262del | 3'UTR (DEL) | VAF 9/79 reads (11%) | called by mutect2, pindel, varscan2
- GPRC5B | c.*1928C>T | 3'UTR (SNP) | VAF 12/333 reads (4%) | catalogued as rs1451573964; called by muse, mutect2
- GRAP2 | c.*280T>C | 3'UTR (SNP) | VAF 6/128 reads (5%) | catalogued as rs1008634550; called by muse, mutect2
- HAND2 | c.-432G>A | 5'UTR (SNP) | VAF 65/155 reads (42%) | called by muse, mutect2, varscan2
- HDAC9 | c.1722+2203G>T | Intron (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- HDAC9 | c.1722+2204A>T | Intron (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- HGSNAT | c.*2480T>G | 3'UTR (SNP) | VAF 10/100 reads (10%) | called by muse, mutect2
- HIPK2 | c.*2959G>A | 3'UTR (SNP) | VAF 9/105 reads (9%) | called by muse, mutect2
- HNRNPU | c.634+1129C>T | Intron (SNP) | VAF 58/167 reads (35%) | catalogued as rs779983935, COSV51692635; called by muse, mutect2, varscan2
- HPCAL4 | c.*2128C>T | 3'UTR (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- IGSF5 | c.*414T>C | 3'UTR (SNP) | VAF 12/66 reads (18%) | called by muse, mutect2, varscan2
- IL17RD | c.*5262G>C | 3'UTR (SNP) | VAF 20/52 reads (38%) | catalogued as rs1403803464; called by muse, mutect2, varscan2
- ISCA1 | c.*751_*752del | 3'UTR (DEL) | VAF 7/65 reads (11%) | called by mutect2, pindel
- ISG20L2 | chr1:156728578 C>A | 5'Flank (SNP) | VAF 14/29 reads (48%) | called by muse, mutect2, varscan2
- MARCHF7 | c.*1424A>G | 3'UTR (SNP) | VAF 13/100 reads (13%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851314 G>A | 5'Flank (SNP) | VAF 59/162 reads (36%) | catalogued as rs573318832; called by muse, mutect2, varscan2
- NTRK3 | c.*6018T>C | 3'UTR (SNP) | VAF 8/94 reads (9%) | catalogued as rs1195896835; called by muse, mutect2
- OTULIN | c.*3275T>C | 3'UTR (SNP) | VAF 20/56 reads (36%) | called by muse, mutect2, varscan2
- PAPPA2 | c.*1082C>T | 3'UTR (SNP) | VAF 6/95 reads (6%) | catalogued as rs1557908180; called by muse, mutect2
- PARD3 | c.*454T>A | 3'UTR (SNP) | VAF 8/126 reads (6%) | called by muse, mutect2
- PLEK | c.*1609G>T | 3'UTR (SNP) | VAF 11/71 reads (15%) | called by muse, mutect2, varscan2
- POU2AF1 | c.*895T>A | 3'UTR (SNP) | VAF 78/203 reads (38%) | called by muse, mutect2, varscan2
- PPIL3 | c.*258A>G | 3'UTR (SNP) | VAF 46/103 reads (45%) | called by muse, mutect2, varscan2
- PPP2R5C | c.95-20463A>G | Intron (SNP) | VAF 55/160 reads (34%) | catalogued as rs1273843156; called by muse, mutect2, varscan2
- PRRC1 | c.1128+1742T>A | Intron (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- PYHIN1 | c.579+512G>A | Intron (SNP) | VAF 23/170 reads (14%) | called by muse, mutect2, varscan2
- RAG2 | chr11:36590413 G>A | 3'Flank (SNP) | VAF 101/265 reads (38%) | catalogued as rs747019244; called by muse, mutect2, varscan2
- SAMD4A | c.*1743T>G | 3'UTR (SNP) | VAF 6/43 reads (14%) | catalogued as rs1046587665; called by muse, varscan2
- SH3KBP1 | c.*785A>C | 3'UTR (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- SPIDR | c.525+74G>T | Intron (SNP) | VAF 6/38 reads (16%) | catalogued as rs1554571258; called by muse, varscan2
- STIMATE | c.*2488_*2507del | 3'UTR (DEL) | VAF 7/77 reads (9%) | catalogued as COSV104422124; called by mutect2, pindel
- TACC2 | c.5835-2389G>A | Intron (SNP) | VAF 14/118 reads (12%) | called by muse, mutect2, varscan2
- TEX2 | c.3262-91C>A | Intron (SNP) | VAF 27/55 reads (49%) | called by muse, mutect2, varscan2
- TFAP2A | chr6:10397772 C>T | 3'Flank (SNP) | VAF 31/85 reads (36%) | called by muse, mutect2, varscan2
- UBE2L6 | c.27+357C>A | Intron (SNP) | VAF 57/132 reads (43%) | called by muse, mutect2, varscan2
- USP31 | c.*563G>A | 3'UTR (SNP) | VAF 6/83 reads (7%) | called by muse, mutect2
- UVSSA | c.*8939G>A | 3'UTR (SNP) | VAF 8/22 reads (36%) | catalogued as rs759644883, COSV99081932; called by muse, varscan2
- WDR41 | c.*280C>T | 3'UTR (SNP) | VAF 17/84 reads (20%) | called by muse, mutect2, varscan2
- ZFP37 | c.*2315A>C | 3'UTR (SNP) | VAF 46/102 reads (45%) | called by muse, mutect2, varscan2
- ZNF561 | c.*528G>C | 3'UTR (SNP) | VAF 4/66 reads (6%) | called by muse, mutect2
